Somatic mutation profile of cancer-model specimen HCM-CSHL-0853-C56-85D (3D Organoid, passage 5; aliquot HCM-CSHL-0853-C56-85D-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d6fff6d-c7a5-455e-8a31-9541d44b0d7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0853-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0853-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91d1fffc-0a47-49fb-9c89-680ce0e305ce

The open-access MAF lists 54 somatic variants for this specimen: 39 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 13, 5'Flank 1, Frame Shift Ins 1, Frame Shift Del 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 185/203 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP2B3 | c.2138G>A p.R713Q | Missense Mutation (SNP) | VAF 113/810 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1557013353; called by muse, mutect2, varscan2
- C2CD2L | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 375/1183 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as rs940210543; called by muse, mutect2, varscan2
- CFAP47 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 250/296 reads (84%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs760933446, COSV52884417; called by muse, mutect2, varscan2
- CIP2A | c.821A>G p.Y274C | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367941403; called by muse, mutect2, varscan2
- CNOT1 | c.4196G>A p.R1399Q | Missense Mutation (SNP) | VAF 55/243 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55320287; called by muse, mutect2, varscan2
- CTNNA2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV58173470; called by muse, mutect2, varscan2
- DOCK8 | c.6136C>A p.L2046I | Missense Mutation (SNP) | VAF 42/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs747086561; called by muse, mutect2, varscan2
- FAM160A2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 102/420 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768160220; called by muse, mutect2, varscan2
- FLT3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201208287, COSV54046882, COSV54065904; called by muse, mutect2, varscan2
- MICU1 | c.941G>A p.R314H (on ENST00000361114 / NM_001195518.2; = p.R320H on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs1216877724; called by muse, mutect2
- NOP9 | c.1624C>T p.R542C | Missense Mutation (SNP) | VAF 23/351 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs762627775; called by muse, mutect2
- PHKA2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1202167585, COSV66052129; called by muse, mutect2, varscan2
- PPFIA4 | c.2323G>C p.D775H (on ENST00000447715; = p.D776H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 219/386 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs774650502; called by muse, mutect2, varscan2
- RXFP2 | c.541T>A p.F181I | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53641074; called by muse, mutect2
- TMEM175 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 126/408 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs577438263, COSV53279397; called by muse, varscan2
- UNC5D | c.2761G>A p.A921T | Missense Mutation (SNP) | VAF 59/625 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs568619133; called by muse, mutect2
- ZKSCAN8 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 26/790 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.075); catalogued as COSV57637055, COSV57638573; called by muse, mutect2
- BEST2 | c.181T>A p.Y61N | Missense Mutation (SNP) | VAF 81/306 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CETP | c.886C>A p.Q296K | Missense Mutation (SNP) | VAF 32/281 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CFAP65 | c.5441T>C p.I1814T | Missense Mutation (SNP) | VAF 60/842 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- CFH | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG4 | c.2564G>T p.G855V | Missense Mutation (SNP) | VAF 106/654 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); called by muse, varscan2
- CSPG4 | c.2563G>C p.G855R | Missense Mutation (SNP) | VAF 112/700 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- F9 | c.371A>T p.E124V | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.729); called by muse, mutect2
- FBN3 | c.6535T>A p.F2179I | Missense Mutation (SNP) | VAF 22/269 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- FRRS1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 51/243 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- GRSF1 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 170/382 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GUCY1A2 | c.2134T>C p.S712P | Missense Mutation (SNP) | VAF 42/714 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2
- ITIH4 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 137/150 reads (91%) | SIFT tolerated (0.19); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- NDUFS4 | c.422dup p.N141Kfs*6 | Frame Shift Ins (INS) | VAF 40/142 reads (28%) | called by mutect2, varscan2
- PLXNA3 | c.2511C>A p.C837* | Nonsense Mutation (SNP) | VAF 119/1011 reads (12%) | called by muse, mutect2, varscan2
- PRSS36 | c.2477G>A p.S826N | Missense Mutation (SNP) | VAF 295/374 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RCN3 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEC24D | c.2037T>A p.N679K | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.009); called by muse, mutect2
- SPATA18 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 235/458 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- TNKS1BP1 | c.2673_2682del p.D892Vfs*64 | Frame Shift Del (DEL) | VAF 72/661 reads (11%) | called by mutect2, pindel, varscan2
- ZNF773 | c.350A>T p.K117M | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); called by muse, mutect2
- ZNF835 | c.347G>C p.G116A | Missense Mutation (SNP) | VAF 18/447 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- AP3B1 | c.1932C>T p.P644= | Silent (SNP) | VAF 103/110 reads (94%) | catalogued as rs368771979; called by muse, mutect2, varscan2
- ATP6V1C1 | c.1146G>A p.K382= | Silent (SNP) | VAF 54/864 reads (6%) | catalogued as rs1047612129; called by muse, mutect2
- BABAM2 | c.1125G>A p.E375= | Silent (SNP) | VAF 143/315 reads (45%) | called by muse, mutect2, varscan2
- BACE1 | c.534C>T p.G178= | Silent (SNP) | VAF 72/625 reads (12%) | catalogued as rs755703640; called by muse, mutect2, varscan2
- CATSPER2 | c.711C>T p.A237= | Silent (SNP) | VAF 45/251 reads (18%) | catalogued as COSV58661491; called by muse, mutect2, varscan2
- COL7A1 | c.6897A>G p.G2299= | Silent (SNP) | VAF 40/237 reads (17%) | catalogued as rs749586805; called by muse, mutect2, varscan2
- KIAA1522 | c.777C>A p.T259= (on ENST00000373480 / NM_001198972.2; = p.T318= on NM_020888.3) | Silent (SNP) | VAF 301/718 reads (42%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.867C>T p.N289= | Silent (SNP) | VAF 230/399 reads (58%) | catalogued as rs374654639; called by muse, mutect2, varscan2
- NCAPH | c.687C>T p.N229= | Silent (SNP) | VAF 101/352 reads (29%) | catalogued as rs760742546; called by muse, mutect2, varscan2
- NR0B2 | c.138C>T p.P46= | Silent (SNP) | VAF 141/299 reads (47%) | catalogued as rs370821222; called by muse, mutect2, varscan2
- PACS2 | c.645C>T p.D215= | Silent (SNP) | VAF 34/782 reads (4%) | catalogued as rs781841033; called by muse, mutect2
- PXDN | c.480C>T p.L160= | Silent (SNP) | VAF 36/430 reads (8%) | catalogued as rs1320356614; called by muse, mutect2
- SHOC1 | c.2052G>A p.L684= | Silent (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- HSPB7 | chr1:16019339 del CTGT | 5'Flank (DEL) | VAF 266/639 reads (42%) | called by mutect2, pindel, varscan2
- NXPH3 | c.*2474C>A | 3'UTR (SNP) | VAF 100/583 reads (17%) | catalogued as rs991604254; called by muse, mutect2, varscan2
